Somatic mutation profile of tumor specimen TCGA-90-7769-01A (aliquot TCGA-90-7769-01A-11D-2122-08) from TCGA case TCGA-90-7769, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.5 years (20,276 days).
Specimen TCGA-90-7769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bad8973-a157-45ca-9711-76d1baccdebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-90-7769-10A (Blood Derived Normal), aliquot TCGA-90-7769-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1eccfc42-f8ad-4d8a-a59d-6843dffdac81

The open-access MAF lists 570 somatic variants for this specimen: 448 protein-altering or splice-affecting, 111 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 386, Silent 111, Nonsense Mutation 28, Frame Shift Del 11, Frame Shift Ins 9, Splice Site 9, Intron 5, RNA 5, Nonstop Mutation 2, Splice Region 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 32/42 reads (76%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 49/169 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3109G>T p.A1037S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV99686253; called by muse, mutect2, varscan2
- ACACB | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); catalogued as rs757630628, COSV100623076; called by muse, mutect2, varscan2
- ACSM2A | c.350C>A p.P117H (on ENST00000219054; = p.P38H on NM_001308169.2) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525426; called by muse, mutect2, varscan2
- ADAM2 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.401); catalogued as COSV99697589; called by muse, mutect2, varscan2
- ADAMTS19 | c.3266A>C p.E1089A | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV50739931, COSV99179401; called by muse, mutect2, varscan2
- ADAMTS6 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs555737820, COSV58685132; called by muse, mutect2, varscan2
- ADCY2 | c.2642A>T p.Q881L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100603298; called by muse, mutect2, varscan2
- ADD1 | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | catalogued as COSV99296677; called by muse, mutect2, varscan2
- ADGRB1 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs371544443, COSV60103429; called by muse, mutect2, varscan2
- ADTRP | c.657G>T p.W219C | Missense Mutation (SNP) | VAF 85/138 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99995364; called by muse, mutect2, varscan2
- AFDN | c.5368A>C p.T1790P (on ENST00000447894 / NM_001366320.1; = p.T1709P on NM_001207008.1) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs751471461, COSV100653188; called by muse, mutect2, varscan2
- AK7 | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99967373; called by muse, mutect2, varscan2
- AKAP13 | c.1594A>T p.S532C | Missense Mutation (SNP) | VAF 100/138 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.43); catalogued as COSV100774090; called by muse, mutect2, varscan2
- AKAP13 | c.4201G>A p.D1401N | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100774091; called by muse, mutect2, varscan2
- AKR1A1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV100698761; called by muse, mutect2, varscan2
- ALMS1 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100040709, COSV100042952; called by muse, mutect2, varscan2
- ALX3 | c.631C>A p.R211S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781127904, COSV100873892; called by muse, mutect2, varscan2
- APC | c.6725G>A p.S2242N | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99968776; called by muse, mutect2, varscan2
- APOBEC3F | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as rs761754118, COSV57909966; called by muse, mutect2, varscan2
- APOH | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV99235839; called by muse, mutect2, varscan2
- ARFGEF2 | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100904347; called by muse, mutect2, varscan2
- ARHGEF10L | c.3679G>T p.A1227S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as rs766792968, COSV51434110, COSV99393247; called by muse, mutect2, varscan2
- ARID4A | c.3126G>C p.E1042D | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100794439; called by muse, mutect2, varscan2
- ASB15 | c.503C>G p.T168S | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99306761; called by muse, mutect2, varscan2
- ATAD5 | c.5495C>T p.P1832L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV100035180; called by muse, mutect2, varscan2
- ATF7IP | c.3157G>C p.V1053L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV99661873; called by muse, mutect2, varscan2
- ATP10A | c.4292G>T p.S1431I | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.063); catalogued as COSV100791380; called by muse, mutect2, varscan2
- ATP10A | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63514201; called by muse, mutect2, varscan2
- ATP13A4 | c.3089A>T p.N1030I | Missense Mutation (SNP) | VAF 73/457 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100710478; called by muse, mutect2, varscan2
- AXDND1 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 46/132 reads (35%) | catalogued as COSV100858511; called by muse, mutect2, varscan2
- BAAT | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.524); catalogued as COSV99408570; called by muse, mutect2, varscan2
- BEX3 | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV100244340; called by muse, mutect2, varscan2
- BIRC6 | c.3832A>T p.N1278Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV101428440; called by muse, mutect2, varscan2
- BPIFA3 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV100967087; called by muse, mutect2, varscan2
- BPIFB2 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV50069656, COSV99401517; called by muse, mutect2, varscan2
- BRDT | c.2120G>C p.G707A | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100746496; called by muse, mutect2, varscan2
- BRINP1 | c.1917C>A p.D639E | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99776096; called by muse, mutect2, varscan2
- BRINP1 | c.1501G>T p.V501F | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV56313692, COSV99776097; called by muse, mutect2, varscan2
- BSPRY | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100949546; called by muse, mutect2, varscan2
- C20orf96 | c.1031+2T>C p.X344_splice (on ENST00000360321 / NM_153269.3; = p.X343_splice on NM_080571.1) | Splice Site (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100826757; called by muse, mutect2, varscan2
- C6orf118 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100024731, COSV57818900; called by muse, mutect2, varscan2
- CAMKMT | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV101035022; called by muse, mutect2, varscan2
- CAPN9 | c.1316A>T p.Y439F | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV99680700; called by muse, mutect2, varscan2
- CASP8AP2 | c.3564C>G p.N1188K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV99387222; called by muse, varscan2
- CATSPER1 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV100376085; called by muse, mutect2, varscan2
- CCDC102A | c.1020G>T p.M340I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV99265143; called by muse, mutect2, varscan2
- CCDC159 | c.687A>G p.I229M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99264582; called by muse, mutect2, varscan2
- CCDC172 | c.550+1G>T p.X184_splice | Splice Site (SNP) | VAF 14/18 reads (78%) | catalogued as COSV100319865; called by muse, varscan2
- CCK | c.300G>C p.W100C | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100589049, COSV100589056; called by muse, mutect2, varscan2
- CCT8L2 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV100742887; called by muse, mutect2, varscan2
- CDC123 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99827026; called by muse, mutect2, varscan2
- CDC6 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV99266624; called by muse, mutect2, varscan2
- CDH2 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52284601, COSV99297455; called by muse, mutect2, varscan2
- CENPE | c.3033+1G>A p.X1011_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99478431; called by muse, mutect2, varscan2
- CENPI | c.2148G>T p.W716C | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99515568; called by muse, mutect2, varscan2
- CFAP61 | c.3393C>A p.Y1131* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99845603, COSV99846192; called by muse, mutect2, varscan2
- CHD7 | c.7438A>T p.T2480S | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.098); catalogued as COSV101418322; called by muse, mutect2, varscan2
- CHL1 | c.2042G>T p.R681I (on ENST00000397491 / NM_001253387.1; = p.R697I on NM_006614.4) | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV99851601; called by muse, mutect2, varscan2
- CHST11 | c.575T>A p.L192Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359658; called by muse, mutect2, varscan2
- CLCA2 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100991613, COSV65287884; called by muse, mutect2, varscan2
- CLTC | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99292557; called by muse, mutect2, varscan2
- CMIP | c.460C>T p.H154Y (on ENST00000537098 / NM_198390.2; = p.H60Y on NM_030629.3) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV101607012; called by muse, mutect2, varscan2
- CNOT3 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99652090; called by muse, mutect2, varscan2
- COL11A1 | c.3866C>A p.A1289D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100617261; called by muse, mutect2, varscan2
- COL12A1 | c.3000A>T p.K1000N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100486211; called by muse, mutect2, varscan2
- COL21A1 | c.2230G>T p.V744F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99779273; called by muse, mutect2
- COL22A1 | c.4628C>G p.A1543G | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as COSV100279232; called by muse, mutect2, varscan2
- COL24A1 | c.3629G>C p.G1210A | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993575; called by muse, mutect2, varscan2
- COL25A1 | c.1514C>A p.P505Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101211525; called by muse, mutect2, varscan2
- COL27A1 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.5); catalogued as COSV100621106; called by muse, mutect2, varscan2
- COL6A3 | c.5569G>T p.G1857C | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99799555; called by muse, mutect2, varscan2
- COPB1 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99999716; called by muse, mutect2, varscan2
- CPNE5 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99782971; called by muse, mutect2, varscan2
- CRACD | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs1416423999, COSV99949575; called by muse, mutect2, varscan2
- CRAMP1 | c.2671A>G p.R891G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99246171; called by muse, mutect2, varscan2
- CRBN | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV99214230; called by muse, mutect2, varscan2
- CRTAC1 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV100085777; called by muse, mutect2, varscan2
- CRYAB | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99909899; called by muse, mutect2, varscan2
- CSDE1 | c.907G>T p.D303Y (on ENST00000358528 / NM_001007553.3; = p.D272Y on NM_007158.6) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99795361; called by muse, mutect2, varscan2
- CSMD3 | c.5099C>A p.S1700Y (on ENST00000297405 / NM_001363185.1; = p.S1596Y on NM_052900.3) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs765905017, COSV99839056; called by muse, mutect2, varscan2
- CTNNAL1 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100336627; called by muse, mutect2, varscan2
- CTTNBP2 | c.4898G>A p.S1633N | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99354312; called by muse, mutect2, varscan2
- CYP7A1 | c.288T>A p.D96E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV100052491; called by muse, mutect2, varscan2
- DCAF12L2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV100758685; called by muse, mutect2, varscan2
- DCAF4L2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747432904, COSV60479126, COSV60479633; called by muse, mutect2, varscan2
- DCDC1 | c.4414G>T p.A1472S (on ENST00000597505 / NM_001367979.1; = p.A579S on NM_020869.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100338480; called by muse, varscan2
- DCHS1 | c.7022A>C p.Q2341P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV100202244; called by muse, mutect2, varscan2
- DCP1B | c.1457C>T p.T486I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1334989100, COSV99767649; called by muse, mutect2, varscan2
- DIAPH3 | c.2671G>A p.E891K (on ENST00000400324 / NM_001042517.2; = p.E628K on NM_030932.3) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99933906; called by muse, mutect2, varscan2
- DIO3 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100832156, COSV63774469; called by muse, mutect2, varscan2
- DIP2B | c.3639C>T p.C1213= | Splice Region (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99998835; called by muse, mutect2, varscan2
- DLC1 | c.4340C>A p.T1447N (on ENST00000276297 / NM_001348081.2; = p.T1010N on NM_006094.5) | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52297932, COSV99364083; called by muse, mutect2, varscan2
- DNA2 | c.2529G>T p.E843D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV100622671; called by muse, mutect2, varscan2
- DNAH9 | c.5318G>A p.R1773Q | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759673753, COSV52335166; called by muse, mutect2, varscan2
- DOCK11 | c.2935G>T p.E979* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as COSV52239897, COSV99354193; called by muse, mutect2, varscan2
- DPP10 | c.983G>C p.S328T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs921492150, COSV100068579, COSV99059621; called by muse, mutect2, varscan2
- DRICH1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | catalogued as rs1395818078, COSV100497468; called by muse, mutect2, varscan2
- DTNA | c.406T>A p.L136I | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99313601; called by muse, mutect2, varscan2
- E4F1 | c.1400A>G p.Q467R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.448); catalogued as COSV100065872; called by muse, mutect2, varscan2
- EARS2 | c.619A>T p.R207W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV101492182; called by muse, mutect2, varscan2
- EIF2AK3 | c.2463G>C p.E821D | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100303906; called by muse, mutect2, varscan2
- ELAPOR2 | c.1664A>G p.H555R (on ENST00000450689 / NM_001142749.3; = p.H388R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs373842850; called by muse, mutect2, varscan2
- ELK4 | c.1231A>T p.T411S | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV99222435; called by muse, mutect2, varscan2
- ENPEP | c.2834C>A p.T945N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV99487791; called by muse, mutect2, varscan2
- EPHA2 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466178100, COSV100626193; called by muse, mutect2, varscan2
- EPHA6 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101064004; called by muse, mutect2, varscan2
- ERICH3 | c.3154A>T p.K1052* | Nonsense Mutation (SNP) | VAF 66/198 reads (33%) | catalogued as COSV100444899; called by muse, mutect2, varscan2
- FAM13A | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371982496; called by muse, mutect2, varscan2
- FAM53A | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV100357155; called by muse, mutect2
- FAM83A | c.952C>A p.R318S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV52687424, COSV99414385; called by muse, mutect2, varscan2
- FAM83E | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99572312; called by muse, mutect2, varscan2
- FAT3 | c.2588A>G p.N863S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99967636, COSV99973733; called by muse, mutect2, varscan2
- FBXO32 | c.902T>A p.V301D | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV99785958; called by muse, mutect2, varscan2
- FBXO5 | c.1207T>C p.F403L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV99999882; called by muse, mutect2, varscan2
- FCRL1 | c.892A>C p.T298P | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1238239468, COSV100839833; called by muse, mutect2, varscan2
- FGGY | c.555-2A>T p.X185_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100365220; called by mutect2, varscan2
- FIG4 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100019936; called by muse, mutect2, varscan2
- FLNC | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.796); catalogued as COSV100368356; called by muse, mutect2, varscan2
- FMR1NB | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100975566, COSV100975600; called by muse, mutect2, varscan2
- FOXA3 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867687500, COSV56216885; called by muse, mutect2, varscan2
- FOXD4L3 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1319728935; called by mutect2, varscan2
- FOXP1 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 125/166 reads (75%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100561942; called by muse, mutect2, varscan2
- FRAS1 | c.11884G>A p.V3962M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as COSV99353795; called by muse, varscan2
- FUCA1 | c.846A>T p.K282N | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100992174; called by muse, mutect2, varscan2
- FUT9 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.065); catalogued as COSV100133881; called by muse, mutect2, varscan2
- GABRB1 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.349); catalogued as COSV54981483, COSV99782313; called by muse, mutect2, varscan2
- GBP4 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756135431, COSV63252924; called by muse, mutect2, varscan2
- GCNT1 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301147364, COSV100946594; called by muse, mutect2, varscan2
- GHRHR | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.588); catalogued as COSV100396656; called by muse, mutect2, varscan2
- GHRHR | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100396660; called by muse, mutect2, varscan2
- GIMAP8 | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100217592; called by muse, mutect2, varscan2
- GLRA1 | c.662A>T p.K221M | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99199618; called by muse, mutect2, varscan2
- GNB3 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57530360, COSV99977001; called by muse, mutect2, varscan2
- GOLGA6B | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV101406927; called by mutect2, varscan2
- GOLIM4 | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100463182, COSV58332003; called by muse, mutect2, varscan2
- GPC3 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 121/153 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV100893158; called by muse, mutect2, varscan2
- GPR158 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1005726641, COSV66266193; called by muse, mutect2, varscan2
- GPR45 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99307059; called by muse, mutect2, varscan2
- GPR65 | c.713G>C p.C238S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV99966104; called by muse, mutect2, varscan2
- GPRC5C | c.227G>T p.C76F (on ENST00000652232; = p.C31F on NM_018653.4) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100702927; called by muse, mutect2, varscan2
- GRIA2 | c.2014G>T p.D672Y | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99645083; called by muse, mutect2, varscan2
- GRM8 | c.2665C>A p.L889I | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV100284221; called by muse, mutect2, varscan2
- GRXCR1 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 109/213 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101295710; called by muse, mutect2, varscan2
- GSAP | c.870A>T p.T290= | Splice Region (SNP) | VAF 29/176 reads (16%) | catalogued as COSV99990322; called by muse, mutect2, varscan2
- GSTZ1 | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs199798136, COSV53624321, COSV99374520; called by muse, mutect2, varscan2
- HAL | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99701526; called by muse, mutect2, varscan2
- HAPLN4 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs374285172; called by muse, mutect2
- HCN1 | c.2099C>A p.T700N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.1); catalogued as rs1352995652, COSV100301137; called by muse, mutect2, varscan2
- HCN1 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100301139; called by muse, mutect2, varscan2
- HCN3 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100855721; called by muse, mutect2, varscan2
- HEATR5B | c.4089A>G p.I1363M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99249724; called by muse, mutect2, varscan2
- HECW2 | c.4088A>G p.N1363S | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99647789; called by muse, mutect2, varscan2
- HEPACAM2 | c.745G>T p.D249Y (on ENST00000394468 / NM_001039372.4; = p.D237Y on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100506453, COSV100506641, COSV100506671; called by muse, mutect2, varscan2
- HERC2 | c.4679C>A p.P1560H | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV99875042; called by muse, mutect2, varscan2
- HNMT | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99698966; called by muse, mutect2, varscan2
- HOXA10 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV99385545; called by muse, mutect2, varscan2
- HRC | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV99418094; called by muse, mutect2, varscan2
- HTR5A | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV99839815; called by muse, mutect2, varscan2
- HYDIN | c.9297G>T p.M3099I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV59269745, COSV99993210; called by muse, mutect2, varscan2
- IGF2R | c.597T>G p.D199E | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV100807685; called by muse, mutect2, varscan2
- IGHG2 | c.350C>G p.P117R | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379264810; called by muse, mutect2, varscan2
- IGKC | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs750839696; called by muse, mutect2, varscan2
- IGLV3-27 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as rs557555538; called by muse, mutect2, varscan2
- IL6 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV99331498; called by muse, mutect2
- ILKAP | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 75/120 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.68); catalogued as COSV99611069; called by muse, mutect2, varscan2
- IMPACT | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 50/124 reads (40%) | catalogued as COSV52422959; called by muse, mutect2, varscan2
- IQSEC3 | c.2038C>A p.P680T (on ENST00000538872 / NM_001170738.2; = p.P377T on NM_015232.1) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV100407375; called by muse, mutect2, varscan2
- IRGQ | c.1040A>T p.E347V | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100338201; called by muse, mutect2, varscan2
- JAML | c.529G>C p.A177P (on ENST00000356289 / NM_001098526.2; = p.A167P on NM_153206.3) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV99409611; called by mutect2, varscan2
- JUP | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100159669; called by muse, mutect2, varscan2
- KALRN | c.4198C>G p.R1400G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53756060, COSV53780259, COSV99565542; called by muse, mutect2, varscan2
- KCNH5 | c.925T>A p.F309I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100527151; called by muse, mutect2, varscan2
- KCNIP1 | c.451G>T p.G151* (on ENST00000411494 / NM_001034837.3; = p.G140* on NM_014592.4) | Nonsense Mutation (SNP) | VAF 32/48 reads (67%) | catalogued as COSV100199683, COSV100199946; called by muse, mutect2, varscan2
- KCNJ16 | c.962A>T p.Y321F | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99388472; called by muse, mutect2, varscan2
- KDM3B | c.2946A>G p.I982M | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV100069896; called by muse, mutect2, varscan2
- KIAA1328 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99694697; called by muse, varscan2
- KIAA1549 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1038032360, COSV99651232; called by muse, mutect2, varscan2
- KIAA1755 | c.1748-1G>T p.X583_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99642326; called by muse, mutect2
- KLK2 | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100320004; called by muse, mutect2, varscan2
- KMT2B | c.3293G>T p.G1098V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV99719986; called by muse, mutect2, varscan2
- KRT3 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100527162, COSV58816732; called by muse, mutect2, varscan2
- KRTAP13-4 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100481768; called by muse, mutect2, varscan2
- LAMA5 | c.7868-1G>A p.X2623_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99440986; called by muse, mutect2, varscan2
- LAMA5 | c.4301G>T p.G1434V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99440988; called by muse, mutect2, varscan2
- LARGE1 | c.1673A>G p.Y558C | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100505844; called by muse, mutect2, varscan2
- LARP6 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV100150923; called by muse, mutect2, varscan2
- LATS1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); catalogued as rs752303818, COSV53588346, COSV99486280; called by muse, mutect2, varscan2
- LCT | c.4127G>T p.R1376L | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as COSV99929859; called by muse, mutect2, varscan2
- LENG9 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.084); catalogued as COSV100002861; called by muse, mutect2, varscan2
- LGALS9C | c.599T>A p.V200E | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100055677; called by muse, mutect2, varscan2
- LIG4 | c.2175G>T p.W725C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100799969; called by muse, mutect2, varscan2
- LIMD1 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV56266098, COSV99837036; called by muse, mutect2, varscan2
- LINGO2 | c.1181A>T p.K394M | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV100430807; called by muse, mutect2, varscan2
- LIPC | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100134689; called by muse, mutect2, varscan2
- LMNA | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV100738756; called by muse, mutect2, varscan2
- LPP | c.686A>T p.Q229L | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100447768; called by muse, mutect2, varscan2
- LRRC4C | c.1441G>T p.V481L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as COSV99538813; called by muse, mutect2, varscan2
- LRRC6 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1026750331, COSV51547193, COSV99138184; called by muse, mutect2
- LRRC8A | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99396724; called by muse, mutect2, varscan2
- LRRC8E | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs143032857; called by muse, mutect2, varscan2
- LRRTM3 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100791595; called by muse, mutect2, varscan2
- LSS | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100710963; called by muse, mutect2, varscan2
- LUM | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV99899103; called by muse, mutect2, varscan2
- LYPD4 | c.292_293insA p.P98Hfs*36 | Frame Shift Ins (INS) | VAF 17/85 reads (20%) | catalogued as COSV100419441; called by mutect2, pindel, varscan2
- LYPD6 | c.438A>G p.I146M | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV100493617; called by muse, mutect2, varscan2
- LYPLAL1 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as rs751333669, COSV100859702; called by muse, mutect2, varscan2
- LYST | c.2729G>T p.S910I | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101089843; called by muse, mutect2, varscan2
- MAB21L2 | c.914T>A p.L305Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100462280; called by muse, mutect2, varscan2
- MAGEB2 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100975708; called by muse, mutect2, varscan2
- MAGEL2 | c.3256G>T p.A1086S | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100046042, COSV58568359; called by muse, mutect2, varscan2
- MCHR1 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as COSV99967854; called by muse, mutect2, varscan2
- MED25 | c.2074G>C p.G692R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100457636; called by muse, mutect2
- METTL24 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.135); catalogued as COSV100133480, COSV58821071; called by muse, mutect2, varscan2
- MGAT4C | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1482741387, COSV100153099; called by muse, mutect2, varscan2
- MIA2 | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV99696820; called by muse, mutect2, varscan2
- MPEG1 | c.1333T>C p.C445R | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99915620; called by muse, mutect2, varscan2
- MRPL32 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99785913; called by muse, mutect2
- MSH2 | c.2804G>T p.*935Lext*7 | Nonstop Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as rs876658335, COSV99254140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTHFD1L | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs751475807, COSV100943456, COSV66209127; called by muse, mutect2, varscan2
- MTMR12 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 90/263 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99373767; called by muse, mutect2, varscan2
- MUC16 | c.21763G>C p.V7255L | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV101200370; called by muse, mutect2, varscan2
- MUC17 | c.1965C>G p.D655E | Missense Mutation (SNP) | VAF 132/710 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100074071, COSV100075217; called by muse, mutect2, varscan2
- MUC5B | c.6071C>A p.T2024N | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.833); catalogued as COSV101500512, COSV71591467; called by muse, mutect2, varscan2
- MUC5B | c.12296C>T p.T4099M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as rs367864174; called by muse, mutect2, varscan2
- MUC5B | c.16352G>T p.C5451F | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101500514; called by muse, mutect2, varscan2
- MYH1 | c.4768A>C p.M1590L | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369414239; called by muse, mutect2, varscan2
- MYH6 | c.3623A>C p.Q1208P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100676774; called by muse, mutect2, varscan2
- MYLK2 | c.1422G>T p.M474I | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.555); catalogued as COSV101044860; called by muse, mutect2, varscan2
- MYO1C | c.2876T>G p.I959S (on ENST00000648651 / NM_001080779.2; = p.I924S on NM_033375.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100704456; called by muse, mutect2, varscan2
- NAPEPLD | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV100439934; called by muse, mutect2, varscan2
- NAV2 | c.5888G>T p.S1963I (on ENST00000396087 / NM_001244963.2; = p.S1904I on NM_145117.5) | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV100217276; called by muse, mutect2, varscan2
- NBAS | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 115/217 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs375818821, COSV99870600; called by muse, mutect2, varscan2
- NBN | c.1652G>A p.R551K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55373407; called by muse, mutect2, varscan2
- NCKAP5 | c.5351A>T p.D1784V | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100493132; called by muse, mutect2, varscan2
- NDN | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV100086544; called by muse, mutect2, varscan2
- NEURL4 | c.973G>T p.G325W | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224415; called by muse, mutect2, varscan2
- NF1 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.857); catalogued as COSV100647563; called by muse, mutect2, varscan2
- NFXL1 | c.1421G>C p.R474P | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100216884; called by muse, mutect2, varscan2
- NINL | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780829582, COSV99625688; called by muse, mutect2, varscan2
- NLRP8 | c.3061T>A p.W1021R | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.03); catalogued as COSV52585240; called by muse, mutect2, varscan2
- NPAP1 | c.3317G>T p.G1106V | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); catalogued as COSV100275647; called by muse, mutect2, varscan2
- NPHS1 | c.2491C>G p.R831G | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as CM990969, COSV100800027; called by muse, mutect2, varscan2
- NR2C1 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280553; called by muse, mutect2, varscan2
- NUTM1 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 87/116 reads (75%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100149094; called by muse, mutect2, varscan2
- NWD1 | c.3981C>G p.I1327M | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV60353054; called by muse, mutect2, varscan2
- OBSCN | c.11065G>A p.E3689K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.29); catalogued as COSV99481165; called by muse, mutect2, varscan2
- OGDHL | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100934355, COSV100934397; called by muse, mutect2, varscan2
- OR1J2 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100093308; called by muse, mutect2, varscan2
- OR2T10 | c.474G>C p.M158I | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV100393748; called by muse, mutect2, varscan2
- OR2T4 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV63543323, COSV63543976, COSV63545316; called by muse, mutect2, varscan2
- OR4A16 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs144421988, COSV59043228; called by muse, mutect2, varscan2
- OR4A47 | c.726G>C p.M242I | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764685729, COSV101487080; called by muse, mutect2, varscan2
- OR4C12 | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV100078591; called by muse, mutect2, varscan2
- OR4L1 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59850540; called by muse, mutect2, varscan2
- OR4N2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV100269768; called by muse, varscan2
- OR51I2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs367656709; called by muse, mutect2, varscan2
- OR52I2 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442959; called by muse, mutect2, varscan2
- OR5D14 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100162472; called by muse, mutect2, varscan2
- OR5H15 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 55/578 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100736706, COSV100736780; called by muse, mutect2, varscan2
- OTOGL | c.1736C>T p.S579L (on ENST00000547103; = p.S570L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101509391; called by muse, mutect2
- PALM2AKAP2 | c.739C>T p.H247Y (on ENST00000374531 / NM_001037293.2; = p.H279Y on NM_053016.6) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100093299; called by muse, mutect2, varscan2
- PARP4 | c.3653C>A p.A1218D | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV101131782; called by muse, mutect2
- PARP6 | c.1745G>C p.W582S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99536187; called by muse, mutect2, varscan2
- PAXIP1 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.514); catalogued as rs371953724; called by muse, mutect2, varscan2
- PCDHB5 | c.1616C>G p.A539G | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); catalogued as COSV50652136, COSV99169219; called by muse, mutect2, varscan2
- PCDHGA6 | c.2374C>G p.L792V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV99541704; called by muse, mutect2, varscan2
- PCDHGB2 | c.1603C>A p.R535S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs1860251, COSV53902712, COSV54011944; called by muse, mutect2
- PCF11 | c.3179G>T p.G1060V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100018731; called by muse, mutect2, varscan2
- PCK1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100100637; called by muse, mutect2, varscan2
- PCLO | c.9457G>A p.D3153N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV100434404; called by muse, mutect2, varscan2
- PDE3A | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs370722557, COSV100762238, COSV100762421; called by muse, mutect2, varscan2
- PDPR | c.2312T>A p.I771N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as COSV99848537; called by muse, mutect2, varscan2
- PDZRN3 | c.2459C>G p.P820R | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as COSV99730644; called by muse, mutect2, varscan2
- PEG3 | c.4036G>T p.V1346F | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99689504; called by muse, mutect2, varscan2
- PHOSPHO2 | c.227C>G p.P76R | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99775972; called by muse, mutect2, varscan2
- PLA1A | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV56333478, COSV99845935; called by muse, mutect2, varscan2
- PLEKHA7 | c.2987A>T p.D996V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.368); catalogued as COSV100261960; called by muse, mutect2, varscan2
- PLEKHA7 | c.2173G>C p.V725L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100850326; called by muse, mutect2, varscan2
- PLEKHG5 | c.2819C>T p.S940L (on ENST00000400915 / NM_001042663.3; = p.S903L on NM_020631.6) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100556948; called by muse, mutect2
- PLXNA2 | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100885620; called by muse, mutect2, varscan2
- POLD2 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV99788921; called by muse, mutect2, varscan2
- POLE | c.5317G>C p.G1773R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.094); catalogued as COSV100267322; called by muse, mutect2, varscan2
- POLR2I | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs1007746111, COSV99387545; called by muse, mutect2, varscan2
- POLR3B | c.1604A>G p.N535S | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99943580; called by muse, mutect2, varscan2
- POLR3B | c.2083+1G>T p.X695_splice | Splice Site (SNP) | VAF 22/78 reads (28%) | catalogued as CS1411455, COSV99943581; called by muse, mutect2, varscan2
- PPAT | c.358del p.A120Hfs*7 | Frame Shift Del (DEL) | VAF 31/177 reads (18%) | catalogued as COSV51705832; called by pindel, varscan2
- PPM1B | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs1468853901, COSV99175838; called by muse, mutect2, varscan2
- PRAM1 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99067414; called by muse, varscan2
- PRDM9 | c.8C>G p.P3R | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV99690053, COSV99690693; called by muse, mutect2, varscan2
- PRKD1 | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100120917; called by muse, mutect2, varscan2
- PTPN4 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); catalogued as COSV99750577; called by muse, mutect2, varscan2
- PTPRE | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99618314; called by muse, mutect2, varscan2
- RAD21 | c.765G>T p.L255F | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1438835712, COSV99815373; called by muse, mutect2, varscan2
- RAD51C | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs777554369, COSV99542709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASGRP4 | c.1860G>C p.E620D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV99385057; called by muse, mutect2, varscan2
- RAVER2 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99605406; called by muse, mutect2, varscan2
- RECK | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100937540; called by muse, mutect2, varscan2
- RECQL | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV101389126; called by muse, mutect2, varscan2
- RELN | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.945); catalogued as rs1294568040, COSV100634152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV3L | c.6424G>A p.D2142N | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100725369; called by muse, mutect2, varscan2
- RGS17 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99243136; called by muse, mutect2, varscan2
- RORC | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs1003218627, COSV100562002; called by muse, mutect2, varscan2
- RP1 | c.3608T>A p.M1203K | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1171900860, COSV99608067; called by muse, mutect2, varscan2
- RPGRIP1L | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100046523; called by muse, mutect2, varscan2
- RRP8 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99601965; called by muse, mutect2, varscan2
- RTL3 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100329911; called by muse, mutect2, varscan2
- RUVBL1 | c.757G>T p.G253* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100494226; called by muse, mutect2, varscan2
- RXFP2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243388453, COSV53637789; called by muse, mutect2, varscan2
- RYR1 | c.8581G>A p.D2861N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs138647599; called by muse, mutect2, varscan2
- SAMD9L | c.2680A>C p.S894R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV100560896; called by muse, mutect2, varscan2
- SCARA3 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV100106914; called by muse, mutect2, varscan2
- SCN1A | c.4662C>A p.N1554K (on ENST00000303395 / NM_001202435.3; = p.N1543K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD117679, COSV100321093; called by muse, mutect2, varscan2
- SCN3A | c.5182C>G p.P1728A | Missense Mutation (SNP) | VAF 96/265 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV99327523; called by muse, mutect2, varscan2
- SCN8A | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV100634010; called by muse, mutect2, varscan2
- SDK1 | c.2554G>T p.G852C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754180345, COSV101269574; called by muse, mutect2, varscan2
- SEC63 | c.962A>C p.D321A | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100938432; called by muse, mutect2, varscan2
- SERTAD1 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100781694; called by muse, mutect2, varscan2
- SETX | c.4365A>C p.E1455D | Missense Mutation (SNP) | VAF 119/198 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99810232; called by muse, mutect2, varscan2
- SF3A3 | c.1220A>T p.N407I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100885655, COSV65955933; called by muse, mutect2, varscan2
- SH2D1A | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758329; called by muse, mutect2, varscan2
- SHANK2 | c.5345C>T p.P1782L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99574953; called by muse, mutect2, varscan2
- SIM1 | c.2301A>G p.*767Wext*17 | Nonstop Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as rs1247546408, COSV99492513; called by muse, mutect2, varscan2
- SIN3B | c.2440G>T p.E814* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99931855; called by muse, mutect2, varscan2
- SIRPG | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.652); catalogued as COSV99403834; called by muse, mutect2
- SLC13A5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99545778; called by muse, mutect2, varscan2
- SLC17A8 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs773887574, COSV100035683, COSV60121619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871002; called by muse, varscan2
- SLC33A1 | c.1482+1G>C p.X494_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100848311; called by muse, mutect2
- SLC39A12 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66202829; called by muse, mutect2, varscan2
- SLC43A2 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100025229, COSV56769075; called by muse, mutect2, varscan2
- SLC5A2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1555495710, COSV100392933, COSV57892238; called by muse, mutect2, varscan2
- SLC9A2 | c.2126C>A p.P709H | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780751618, COSV99296454; called by muse, mutect2, varscan2
- SLCO1B1 | c.1563G>T p.L521F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747056749, COSV57012500; called by muse, mutect2, varscan2
- SLITRK2 | c.2438G>T p.G813V | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100157933; called by muse, mutect2, varscan2
- SLITRK3 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99579573; called by muse, mutect2, varscan2
- SMARCAD1 | c.2974C>T p.Q992* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100758976; called by muse, varscan2
- SMR3A | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV99895738; called by muse, mutect2, varscan2
- SND1 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100690689; called by muse, mutect2, varscan2
- SPAG17 | c.4264G>C p.A1422P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100309631, COSV60471649; called by muse, mutect2, varscan2
- SPARCL1 | c.1938G>C p.E646D | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99215718; called by muse, mutect2, varscan2
- SPARCL1 | c.1519G>T p.G507* | Nonsense Mutation (SNP) | VAF 77/217 reads (35%) | catalogued as COSV99215721; called by muse, mutect2, varscan2
- SPATS1 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99913507; called by muse, mutect2, varscan2
- SPG7 | c.1081G>T p.V361L (on ENST00000268704; = p.V368L on NM_003119.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746289118, COSV99245103; called by muse, mutect2, varscan2
- STAT4 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs1003116465, COSV100636106; called by muse, mutect2, varscan2
- STPG2 | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV99760179; called by muse, mutect2, varscan2
- SUGP2 | c.2386G>T p.A796S | Missense Mutation (SNP) | VAF 141/303 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100432063; called by muse, mutect2, varscan2
- SULT6B1 | c.433A>G p.T145A (on ENST00000535679 / NM_001367551.1; = p.T107A on NM_001032377.2) | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV99573226; called by muse, mutect2, varscan2
- SYNE1 | c.21728G>C p.R7243T (on ENST00000367255 / NM_182961.4; = p.R7172T on NM_033071.3) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.295); catalogued as COSV99570571; called by muse, mutect2, varscan2
- SYNE2 | c.3181G>T p.G1061* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100648060; called by muse, mutect2, varscan2
- TAAR2 | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99255696; called by muse, mutect2, varscan2
- TAF1B | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs781060198, COSV99722281; called by muse, mutect2, varscan2
- TAGAP | c.1974C>A p.H658Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV100487521, COSV57852222; called by muse, mutect2, varscan2
- TAS2R41 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101281498; called by muse, mutect2, varscan2
- TBXAS1 | c.187T>C p.F63L | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99695614; called by muse, mutect2, varscan2
- TCHHL1 | c.1050G>T p.L350F | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.047); catalogued as COSV100916560; called by muse, mutect2, varscan2
- TDRD9 | c.3169G>A p.V1057I | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs575819052, COSV100175338, COSV59158223; called by muse, mutect2, varscan2
- THNSL2 | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100147547; called by muse, mutect2, varscan2
- THSD7B | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99753913; called by muse, mutect2, varscan2
- THSD7B | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 126/361 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV99753916; called by muse, mutect2, varscan2
- TLR4 | c.434C>A p.P145H (on ENST00000355622 / NM_138554.5; = p.P105H on NM_003266.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV100790666; called by muse, mutect2, varscan2
- TM4SF5 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762941132, COSV99564745; called by muse, mutect2, varscan2
- TMC3 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as COSV100845941; called by muse, varscan2
- TMED6 | c.602T>A p.V201E | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99650814; called by muse, mutect2, varscan2
- TMEM135 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.236); catalogued as COSV100449863; called by muse, mutect2, varscan2
- TMEM170A | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.331); catalogued as rs1222247963, COSV100713257, COSV62923385; called by muse, mutect2, varscan2
- TNNI3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs371000425, COSV61275260, COSV61276871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC6A | c.5314G>T p.G1772C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100170242; called by muse, mutect2, varscan2
- TPTE | c.1162C>A p.P388T (on ENST00000618007 / NM_199261.4; = p.P370T on NM_199259.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759137049; called by muse, mutect2, varscan2
- TRIM60 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as rs754880761, COSV61970459; called by muse, mutect2, varscan2
- TRIO | c.8387A>G p.Y2796C | Missense Mutation (SNP) | VAF 83/105 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702647; called by muse, mutect2, varscan2
- TRPM1 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99856194; called by muse, mutect2, varscan2
- TRPV5 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs199871524, COSV54685631; called by muse, mutect2, varscan2
- TSPAN18 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV100418801; called by muse, mutect2, varscan2
- TTC23 | c.845C>A p.S282* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100018990, COSV50441166; called by muse, mutect2, varscan2
- TTN | c.88265G>A p.W29422* (on ENST00000591111; = p.W21998* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 116/325 reads (36%) | catalogued as COSV100619823; called by muse, mutect2, varscan2
- TTN | c.65678C>A p.S21893Y (on ENST00000591111; = p.S14469Y on NM_003319.4) | Missense Mutation (SNP) | VAF 134/428 reads (31%) | PolyPhen possibly damaging (0.502); catalogued as COSV100619827, COSV100620222; called by muse, mutect2, varscan2
- TTN | c.61761T>A p.Y20587* (on ENST00000591111; = p.Y13163* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100619829; called by muse, mutect2, varscan2
- TTN | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | PolyPhen benign (0.081); catalogued as COSV100619832, COSV59905664; called by muse, mutect2, varscan2
- TUT4 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1392649050, COSV99932536; called by muse, mutect2, varscan2
- TXNDC2 | c.845G>T p.G282V (on ENST00000306084 / NM_001098529.2; = p.G215V on NM_032243.6) | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as rs370301829, COSV100046338; called by muse, mutect2, varscan2
- UBE3C | c.2896G>A p.G966S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100780014; called by muse, mutect2, varscan2
- UBR5 | c.4559C>T p.P1520L | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); catalogued as COSV99641444; called by muse, mutect2
- UGGT1 | c.2236+1del | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | catalogued as COSV99391034; called by mutect2, pindel, varscan2
- USF1 | c.634C>G p.R212G | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99041450, COSV99231138; called by muse, mutect2, varscan2
- USH2A | c.9517T>C p.C3173R | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100238043; called by muse, mutect2, varscan2
- USP29 | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV99518290; called by muse, mutect2, varscan2
- UTP20 | c.3851T>A p.I1284K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV99881974; called by muse, mutect2, varscan2
- UTS2B | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 221/291 reads (76%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100484280; called by muse, mutect2, varscan2
- VCAN | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54114647, COSV99425408; called by muse, mutect2, varscan2
- VN1R4 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV60805198; called by muse, mutect2, varscan2
- VWA3B | c.2474C>T p.S825L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101346080; called by muse, mutect2, varscan2
- VWA5A | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV100827913; called by muse, mutect2, varscan2
- WDR18 | c.37T>A p.S13T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1240900377, COSV99242932; called by muse, mutect2, varscan2
- WDR64 | c.855T>A p.Y285* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100843861; called by muse, mutect2, varscan2
- WFDC9 | c.125G>A p.W42* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100385665; called by muse, mutect2, varscan2
- XRN2 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101018480; called by muse, mutect2, varscan2
- ZBED4 | c.1592C>A p.A531E | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV99351402; called by muse, mutect2, varscan2
- ZBED9 | c.3358C>G p.Q1120E | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV101509313; called by muse, mutect2, varscan2
- ZBTB20 | c.529G>C p.A177P (on ENST00000474710 / NM_001164342.2; = p.A104P on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100614271; called by muse, mutect2, varscan2
- ZDBF2 | c.3280dup p.I1094Nfs*14 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | catalogued as rs765952396; called by mutect2, varscan2
- ZEB2 | c.2297T>A p.F766Y | Missense Mutation (SNP) | VAF 138/280 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as COSV100356413; called by muse, mutect2, varscan2
- ZFP37 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as COSV100953291; called by muse, mutect2, varscan2
- ZFP42 | c.886A>T p.I296F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100478986; called by muse, mutect2, varscan2
- ZFR2 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1006468427, COSV99507597; called by muse, mutect2, varscan2
- ZIC4 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV101268046; called by muse, mutect2, varscan2
- ZNF208 | c.2617C>A p.P873T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.452); catalogued as COSV101237098; called by muse, mutect2, varscan2
- ZNF239 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT tolerated (1); PolyPhen possibly damaging (0.62); catalogued as COSV100021845; called by muse, mutect2, varscan2
- ZNF284 | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101399029; called by muse, mutect2, varscan2
- ZNF43 | c.1148C>A p.S383* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100731869; called by muse, mutect2, varscan2
- ZNF496 | c.378A>T p.R126S | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99665870; called by muse, mutect2, varscan2
- ZNF506 | c.345dup p.G116Rfs*3 | Frame Shift Ins (INS) | VAF 41/83 reads (49%) | catalogued as rs1409120867; called by mutect2, varscan2
- ZNF529 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100485309; called by muse, mutect2, varscan2
- ZNF560 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.343); catalogued as rs977693604, COSV100038764; called by muse, mutect2, varscan2
- ZNF607 | c.1828A>T p.I610F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV100777930; called by muse, mutect2, varscan2
- ZNF667 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174917115, COSV99410674; called by muse, mutect2, varscan2
- ZNF680 | c.1043A>T p.K348I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100549238; called by muse, mutect2, varscan2
- ZNF681 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101267505; called by muse, mutect2, varscan2
- ZNF76 | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99987781; called by muse, mutect2, varscan2
- ZNF92 | c.1532G>C p.C511S (on ENST00000328747 / NM_152626.4; = p.C442S on NM_007139.4) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100165632, COSV100165874; called by muse, mutect2
- ZSCAN18 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1290125681, COSV99559539; called by muse, mutect2, varscan2
- ZSCAN18 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1157994327, COSV53730716, COSV99559540; called by muse, mutect2, varscan2
- ABCC12 | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2
- AHCYL1 | c.886dup p.S296Ffs*26 | Frame Shift Ins (INS) | VAF 43/123 reads (35%) | called by mutect2, pindel, varscan2
- FBN3 | c.6698_6699del p.A2233Vfs*20 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by pindel, varscan2
- FBXO21 | c.1227_1236del p.D410Ifs*36 (on ENST00000330622 / NM_033624.3; = p.D410Ifs*41 on NM_015002.3) | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- FCGBP | c.11303A>T p.H3768L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- HPSE2 | c.532dup p.R178Kfs*22 | Frame Shift Ins (INS) | VAF 63/118 reads (53%) | called by mutect2, pindel, varscan2
- IGLV3-27 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- KCNV2 | c.399C>G p.S133R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, varscan2
- MMP2 | c.1361del p.G454Afs*44 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- NCAM1 | c.616del p.V206Sfs*3 | Frame Shift Del (DEL) | VAF 34/161 reads (21%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.80_86delinsTATG p.D27_D29delinsVC | In Frame Del (DEL) | VAF 16/36 reads (44%) | called by pindel, varscan2*
- NPAP1 | c.2202del p.Q734Hfs*31 | Frame Shift Del (DEL) | VAF 50/234 reads (21%) | called by mutect2, pindel, varscan2
- P2RY13 | c.804del p.F268Lfs*48 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- PCLO | c.14905dup p.E4969Gfs*3 | Frame Shift Ins (INS) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- POLR2A | c.5902G>T p.E1968* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- RERE | c.1078dup p.D360Gfs*12 | Frame Shift Ins (INS) | VAF 64/226 reads (28%) | called by mutect2, pindel, varscan2
- SH2D5 | c.1119_1120del p.V374Yfs*2 (on ENST00000444387 / NM_001103161.2; = p.V290Yfs*2 on NM_001103160.2) | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.106dup p.T36Nfs*11 | Frame Shift Ins (INS) | VAF 75/484 reads (15%) | called by mutect2, pindel, varscan2
- SYTL5 | c.1051dup p.A351Gfs*11 | Frame Shift Ins (INS) | VAF 29/58 reads (50%) | called by mutect2, pindel, varscan2
- TAGLN | c.36del p.E13Kfs*23 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel
- TRAV22 | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- UNC79 | c.1054del p.X352_splice (on ENST00000393151 / NM_001346218.2; = p.X175_splice on NM_020818.5) | Splice Site (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- ZPBP2 | c.62del p.P21Rfs*24 | Frame Shift Del (DEL) | VAF 101/237 reads (43%) | called by mutect2, pindel, varscan2
- AATK | c.3093G>A p.G1031= (on ENST00000326724 / NM_001080395.3; = p.G928= on NM_004920.2) | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100352972; called by muse, mutect2, varscan2
- ABCA13 | c.11922A>T p.R3974= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV101447019; called by muse, mutect2, varscan2
- ACSM2B | c.1425C>T p.P475= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV100312893; called by muse, mutect2, varscan2
- ADAM17 | c.1668G>T p.P556= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV100176364; called by muse, mutect2, varscan2
- ADAMTS3 | c.3315C>T p.S1105= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99711483; called by muse, mutect2, varscan2
- ADGRG4 | c.4398G>A p.L1466= | Silent (SNP) | VAF 97/124 reads (78%) | catalogued as COSV99795966; called by muse, mutect2, varscan2
- AMD1 | c.738A>C p.P246= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100924503; called by muse, mutect2, varscan2
- ANKFN1 | c.327G>A p.G109= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV100593800; called by muse, mutect2, varscan2
- ARMC7 | c.351T>G p.S117= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99822685; called by muse, mutect2, varscan2
- ASL | c.1222C>T p.L408= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV100508865, COSV100508934; called by muse, mutect2, varscan2
- ATP11A | c.1488G>C p.P496= | Silent (SNP) | VAF 63/146 reads (43%) | catalogued as COSV52115723, COSV99369168; called by muse, mutect2, varscan2
- ATP1A4 | c.3081G>T p.T1027= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100927325, COSV63624441; called by muse, mutect2
- ATP4A | c.360C>A p.A120= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99382797; called by muse, mutect2, varscan2
- AZGP1 | c.435T>A p.I145= | Silent (SNP) | VAF 162/385 reads (42%) | catalogued as COSV99448056; called by muse, mutect2, varscan2
- BAIAP2 | c.834G>T p.P278= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV58334076; called by muse, mutect2, varscan2
- BCR | c.3633G>A p.L1211= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV100006111; called by muse, mutect2, varscan2
- BOD1L1 | c.5577C>T p.G1859= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs146332136; called by muse, mutect2
- C22orf31 | c.556C>A p.R186= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as COSV99326467; called by muse, mutect2, varscan2
- C8orf74 | c.462C>A p.A154= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV100262170, COSV58753498; called by muse, mutect2, varscan2
- CCDC116 | c.675G>A p.L225= | Silent (SNP) | VAF 77/333 reads (23%) | catalogued as COSV53037857, COSV99488967; called by muse, mutect2, varscan2
- CCDC172 | c.192C>T p.F64= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV100319864; called by muse, mutect2, varscan2
- CHP2 | c.207C>T p.S69= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100270205, COSV55649726; called by muse, mutect2, varscan2
- CLVS1 | c.858G>T p.T286= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100370226, COSV57973507; called by muse, mutect2, varscan2
- COL22A1 | c.1258C>A p.R420= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs143147850, COSV100279233; called by muse, mutect2, varscan2
- COLEC11 | c.138G>C p.A46= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99363201, COSV99363407; called by muse, varscan2
- CYP11A1 | c.1215A>C p.R405= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99166066; called by muse, mutect2, varscan2
- CYP11A1 | c.489C>A p.A163= | Silent (SNP) | VAF 63/74 reads (85%) | catalogued as COSV51430860; called by muse, mutect2, varscan2
- DCC | c.2502C>A p.P834= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV100501275; called by muse, mutect2, varscan2
- DEFB129 | c.549G>A p.Q183= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99857489; called by muse, mutect2, varscan2
- DIDO1 | c.3873A>G p.T1291= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as rs199561380; called by muse, mutect2, varscan2
- DLGAP1 | c.1116G>A p.R372= | Silent (SNP) | VAF 16/159 reads (10%) | catalogued as COSV100232377; called by muse, mutect2, varscan2
- DMGDH | c.882G>A p.L294= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV99669209; called by muse, mutect2, varscan2
- DMKN | c.576C>A p.P192= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV100303725; called by muse, mutect2, varscan2
- DNAH11 | c.12267C>T p.A4089= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as rs779248595, COSV100179728; called by muse, mutect2, varscan2
- DNAH7 | c.9669T>A p.I3223= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100416055; called by muse, mutect2, varscan2
- DRD5 | c.816C>T p.C272= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1363311829, COSV100431884; called by muse, mutect2, varscan2
- DYNC1I1 | c.819T>A p.L273= | Silent (SNP) | VAF 206/532 reads (39%) | catalogued as COSV100268734; called by muse, mutect2, varscan2
- EIF4G3 | c.243C>T p.P81= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1363123537, COSV99942911; called by muse, mutect2, varscan2
- ENHO | c.48C>T p.N16= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs368502183; called by muse, mutect2, varscan2
- EYA1 | c.1389C>A p.A463= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100379768, COSV58157648; called by muse, mutect2
- FBXO38 | c.3246C>A p.P1082= (on ENST00000340253 / NM_205836.3; = p.P1007= on NM_030793.5) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV57027300, COSV99693622; called by muse, mutect2, varscan2
- FCGBP | c.12414A>T p.L4138= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- FER1L6 | c.1915C>A p.R639= | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as rs761199319, COSV101206011; called by muse, mutect2, varscan2
- GALNT6 | c.270C>T p.L90= | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as rs1457709001, COSV100695547; called by muse, mutect2, varscan2
- GDF2 | c.447G>A p.E149= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- GLUD2 | c.309C>A p.R103= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV60151667; called by muse, mutect2, varscan2
- GPHA2 | c.252C>A p.S84= | Silent (SNP) | VAF 67/186 reads (36%) | catalogued as COSV51210402, COSV99376260; called by muse, mutect2, varscan2
- GPR19 | c.363C>T p.F121= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs867433626, COSV60124036; called by muse, mutect2, varscan2
- GRM1 | c.756C>A p.G252= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99267182; called by muse, mutect2, varscan2
- GRM6 | c.1861C>A p.R621= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as CM050642, COSV99179689; called by muse, mutect2, varscan2
- GRM6 | c.1542C>T p.P514= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV99179612, COSV99179690; called by muse, mutect2, varscan2
- GTF3C1 | c.315G>A p.E105= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99851490; called by muse, mutect2, varscan2
- HECW1 | c.1935C>A p.A645= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101223949; called by muse, mutect2, varscan2
- HEPHL1 | c.1932C>T p.S644= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs770941688, COSV59892181; called by muse, mutect2, varscan2
- ICE1 | c.4077G>C p.G1359= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99665102; called by muse, mutect2, varscan2
- ITGA3 | c.259C>A p.R87= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99143834; called by muse, mutect2, varscan2
- ITIH3 | c.747T>A p.T249= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV101407009; called by muse, mutect2, varscan2
- KCNJ6 | c.402C>T p.T134= | Silent (SNP) | VAF 82/118 reads (69%) | catalogued as rs772348723, COSV55726405; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDM6B | c.1971G>A p.P657= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs778992684, COSV99641840; called by muse, mutect2, varscan2
- KIF1C | c.3300G>T p.G1100= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV100297225; called by muse, mutect2, varscan2
- KIF2B | c.1578T>A p.S526= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99275713; called by muse, mutect2, varscan2
- KLHL38 | c.567C>T p.L189= | Silent (SNP) | VAF 94/234 reads (40%) | catalogued as COSV100384463; called by muse, mutect2, varscan2
- LNPEP | c.519G>A p.V173= | Silent (SNP) | VAF 72/105 reads (69%) | catalogued as rs758324549, COSV99183561; called by muse, mutect2, varscan2
- LVRN | c.702G>C p.L234= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs766051193, COSV100773560; called by muse, varscan2
- LZTS1 | c.1299C>T p.T433= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV99743095; called by muse, mutect2, varscan2
- MAOA | c.1242G>A p.G414= | Silent (SNP) | VAF 27/30 reads (90%) | catalogued as rs774182469, COSV100108855; called by muse, mutect2, varscan2
- MUC17 | c.3225T>A p.T1075= | Silent (SNP) | VAF 151/738 reads (20%) | catalogued as COSV100074074; called by muse, mutect2, varscan2
- MUC5B | c.6072C>A p.T2024= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs747984329, COSV101500513, COSV71595873; called by muse, mutect2, varscan2
- MYH2 | c.2127C>A p.R709= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV99820479; called by muse, mutect2, varscan2
- MYOM2 | c.729G>A p.A243= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as rs770679429, COSV100037837; called by muse, mutect2, varscan2
- NCAN | c.1881C>G p.S627= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV99387687; called by muse, mutect2, varscan2
- NCOA1 | c.2955A>G p.E985= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as COSV99946511; called by muse, mutect2, varscan2
- NDUFB8 | c.411G>T p.L137= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100144133; called by muse, mutect2, varscan2
- NLRP9 | c.357C>T p.V119= | Silent (SNP) | VAF 33/198 reads (17%) | catalogued as COSV100243199; called by muse, mutect2, varscan2
- NOS1 | c.891C>T p.G297= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100500897; called by muse, mutect2, varscan2
- NUP50 | c.552A>T p.T184= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV100754369; called by muse, mutect2, varscan2
- OBSCN | c.4293C>T p.F1431= | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as rs747196936, COSV52835051; called by muse, mutect2, varscan2
- OR4M1 | c.669C>A p.A223= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as rs1222859124, COSV100271318; called by muse, mutect2, varscan2
- OR5B2 | c.231C>A p.P77= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV100222912; called by muse, mutect2, varscan2
- OR6M1 | c.660T>A p.S220= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100484111; called by muse, mutect2, varscan2
- OR6M1 | c.315G>T p.L105= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100484112; called by muse, mutect2, varscan2
- PCDHGB2 | c.1605C>G p.R535= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs1860252, COSV53902725, COSV53962165; called by muse, mutect2
- PDZD2 | c.204C>T p.I68= | Silent (SNP) | VAF 34/261 reads (13%) | catalogued as COSV56854095, COSV99225681; called by muse, mutect2, varscan2
- PEG3 | c.363G>T p.L121= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV99689505; called by muse, mutect2, varscan2
- PIK3CG | c.411G>T p.L137= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100782996; called by muse, mutect2, varscan2
- PLA2G4E | c.1995C>T p.H665= | Silent (SNP) | VAF 39/53 reads (74%) | catalogued as rs750955524, COSV101268607; called by muse, mutect2, varscan2
- POLG2 | c.714G>T p.S238= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV101604429, COSV73346996; called by muse, mutect2, varscan2
- POTEA | c.150C>T p.D50= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs566931601; called by muse, mutect2, varscan2
- PPFIA1 | c.291C>T p.L97= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV54139474, COSV99557594; called by muse, mutect2, varscan2
- PRAME | c.162G>T p.P54= | Silent (SNP) | VAF 49/150 reads (33%) | catalogued as rs199873817, COSV101287130, COSV67160855; called by muse, mutect2, varscan2
- RASGRP3 | c.930A>T p.I310= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV101274807; called by muse, mutect2, varscan2
- RIC8A | c.36G>T p.T12= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV57314941; called by muse, mutect2, varscan2
- SH3GL2 | c.285G>A p.E95= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs1043446187, COSV101014565; called by muse, mutect2, varscan2
- SP1 | c.1287C>T p.A429= (on ENST00000327443 / NM_138473.3; = p.A422= on NM_003109.1) | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100540730; called by muse, mutect2, varscan2
- ST8SIA4 | c.291G>T p.V97= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99185365; called by muse, mutect2, varscan2
- STXBP5L | c.1929T>C p.T643= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV56539965; called by muse, mutect2, varscan2
- STYXL2 | c.862C>A p.R288= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as rs776576712, COSV99609493; called by muse, mutect2, varscan2
- SUGP2 | c.2799G>T p.L933= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100432061; called by muse, mutect2, varscan2
- SUGP2 | c.684G>A p.K228= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as COSV100432065; called by muse, mutect2, varscan2
- TECTB | c.189C>A p.V63= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101027733; called by muse, mutect2, varscan2
- TPTE | c.594A>G p.R198= (on ENST00000618007 / NM_199261.4; = p.R180= on NM_199259.4) | Silent (SNP) | VAF 5/47 reads (11%) | called by mutect2, varscan2
- TRAJ17 | c.27A>G p.L9= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- TREM1 | c.426C>G p.G142= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99776245; called by muse, mutect2, varscan2
- TREML2 | c.273C>T p.T91= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs1364230279, COSV72439072; called by muse, mutect2, varscan2
- TTN | c.2451T>C p.T817= (on ENST00000591111; = p.T771= on NM_003319.4) | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100619831; called by muse, mutect2, varscan2
- UBE3C | c.1494A>T p.P498= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100780013; called by muse, mutect2, varscan2
- UGT2B15 | c.213T>C p.A71= | Silent (SNP) | VAF 68/293 reads (23%) | catalogued as COSV100592377; called by muse, mutect2, varscan2
- WBP2NL | c.237G>A p.L79= | Silent (SNP) | VAF 55/239 reads (23%) | catalogued as COSV100173853; called by muse, mutect2, varscan2
- WDFY1 | c.9C>T p.A3= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs745385983, COSV99239644; called by muse, mutect2, varscan2
- ZNF12 | c.1173G>T p.S391= (on ENST00000405858 / NM_016265.4; = p.S353= on NM_006956.3) | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100703769, COSV61244335; called by muse, mutect2, varscan2
- ZNF257 | c.120G>T p.L40= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV101448124, COSV71307986; called by muse, mutect2, varscan2
- HOMER3 | c.*149C>T | 3'UTR (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99651166; called by muse, mutect2, varscan2
- MASP1 | c.1303+5177C>T | Intron (SNP) | VAF 71/124 reads (57%) | catalogued as COSV99962522; called by muse, mutect2, varscan2
- MIR519A1 | n.28C>A | RNA (SNP) | VAF 44/253 reads (17%) | catalogued as rs761755160; called by muse, mutect2, varscan2
- OR3A4P | n.380G>T | RNA (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- SCOC-AS1 | n.139+25657C>T | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100639604; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44451G>C | Intron (SNP) | VAF 25/105 reads (24%) | catalogued as COSV101044230, COSV67444132; called by muse, mutect2, varscan2
- SNORD108 | n.71C>A | RNA (SNP) | VAF 52/88 reads (59%) | called by muse, varscan2
- SNORD116-20 | n.75C>A | RNA (SNP) | VAF 183/276 reads (66%) | called by muse, mutect2, varscan2
- SNORD116-7 | n.16C>T | RNA (SNP) | VAF 92/227 reads (41%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7539C>T | Intron (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-533+72G>T | Intron (SNP) | VAF 14/39 reads (36%) | catalogued as rs1381232921, COSV101637465, COSV73947912; called by muse, mutect2, varscan2
